TCGA case TCGA-UW-A7GJ — Kidney Chromophobe (TCGA-KICH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e2c4e773-ed5e-4274-aca6-1e7168d593de

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Renal cell carcinoma, chromophobe type: ICD-O-3 morphology code: 8317/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 52.7 years (19,258 days); Year of diagnosis: 2004; AJCC staging edition: 6th; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,614 days (9.9 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 3,249 days (8.9 years); Disease response: Tumor Free.
- Days to follow up: 3,614 days (9.9 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 15; Tobacco smoking onset year: 1978; Tobacco smoking quit year: 1993.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UW-A7GJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide TCGA-UW-A7GJ-01Z-00-DX1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-UW-A7GJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UW-A7GJ-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide TCGA-UW-A7GJ-11Z-00-DX1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 70; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-UW-A7GJ-11Z: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Lymph nodes examined: No; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,614 days; disease-specific survival: no event (censored), 3,614 days; disease-free interval: no event (censored), 3,614 days; progression-free interval: no event (censored), 3,614 days.
